Somatic mutation profile of tumor specimen TCGA-RC-A7SB-01A (aliquot TCGA-RC-A7SB-01A-21D-A34Z-10) from TCGA case TCGA-RC-A7SB, project TCGA-LIHC (Liver Hepatocellular Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Hepatocellular carcinoma, NOS; Tissue or organ of origin: Liver; AJCC pathologic stage: Stage II; Tumor grade: G2; Age at diagnosis: 53.9 years (19,698 days).
Specimen TCGA-RC-A7SB-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 4bdae878-4130-4b80-8d6b-dddb19d5acb7.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-RC-A7SB-10A (Blood Derived Normal), aliquot TCGA-RC-A7SB-10A-01D-A34Z-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ec10e34c-4adc-4c63-918e-784a039b0b01

The open-access MAF lists 70 somatic variants for this specimen: 47 protein-altering or splice-affecting, 22 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 34, Silent 22, Frame Shift Del 6, Nonsense Mutation 3, Splice Site 3, Splice Region 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.772G>A p.E258K | Missense Mutation (SNP) | VAF 17/23 reads (74%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs121912652, CM900213, COSV52684909, COSV52740428, COSV52828352; ClinVar: uncertain significance / likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- AAR2 | c.691G>A p.D231N | Missense Mutation (SNP) | VAF 13/38 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100299367; called by muse, mutect2, varscan2
- ADAMTS9 | c.566A>T p.Q189L | Missense Mutation (SNP) | VAF 70/148 reads (47%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99899831; called by muse, mutect2, varscan2
- ALG5 | c.925C>T p.R309* | Nonsense Mutation (SNP) | VAF 14/28 reads (50%) | catalogued as COSV53504958; called by muse, mutect2, varscan2
- AMY2A | c.227G>T p.R76I | Missense Mutation (SNP) | VAF 103/287 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV70214335; called by muse, mutect2, varscan2
- ARID1B | c.1652G>A p.G551D | Missense Mutation (SNP) | VAF 32/80 reads (40%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.861); catalogued as COSV99270458; called by muse, mutect2, varscan2
- CDH7 | c.1472G>T p.C491F | Missense Mutation (SNP) | VAF 47/121 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100542769, COSV99064593; called by muse, mutect2, varscan2
- DIO2 | c.640del p.R214Afs*? | Frame Shift Del (DEL) | VAF 16/32 reads (50%) | catalogued as COSV70446063; called by mutect2, varscan2
- DNAH5 | c.13568A>G p.D4523G | Missense Mutation (SNP) | VAF 28/82 reads (34%) | SIFT deleterious (0); PolyPhen benign (0.3); catalogued as COSV99451623; called by muse, mutect2, varscan2
- EGF | c.327+2T>C p.X109_splice | Splice Site (SNP) | VAF 13/24 reads (54%) | catalogued as COSV99491158; called by muse, mutect2, varscan2
- EXOC7 | c.1163A>T p.E388V (on ENST00000335146 / NM_001145297.4; = p.E306V on NM_015219.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 14/32 reads (44%) | SIFT deleterious (0.01); PolyPhen benign (0.069); catalogued as COSV100135481; called by muse, mutect2, varscan2
- GPD1L | c.380G>A p.G127D | Missense Mutation (SNP) | VAF 15/52 reads (29%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.596); catalogued as COSV99245798; called by muse, mutect2, varscan2
- GRM8 | c.2554C>T p.R852C | Missense Mutation (SNP) | VAF 46/106 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.836); catalogued as rs139289550; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- HAPLN1 | c.503G>T p.G168V | Missense Mutation (SNP) | VAF 19/42 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57148967, COSV99165058; called by muse, mutect2, varscan2
- HDGFL2 | c.1450T>C p.F484L | Missense Mutation (SNP) | VAF 4/10 reads (40%) | SIFT deleterious (0.05); PolyPhen benign (0.095); catalogued as COSV100012338; called by muse, mutect2
- HIBCH | c.769A>T p.K257* | Nonsense Mutation (SNP) | VAF 37/86 reads (43%) | catalogued as COSV100676193; called by muse, mutect2, varscan2
- LPO | c.1106-1G>A p.X369_splice | Splice Site (SNP) | VAF 4/33 reads (12%) | catalogued as COSV99229086; called by muse, mutect2
- MAGEL2 | c.3509G>T p.R1170M | Missense Mutation (SNP) | VAF 12/27 reads (44%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as COSV100046062; called by muse, mutect2, varscan2
- MIB1 | c.862A>T p.I288F | Missense Mutation (SNP) | VAF 52/140 reads (37%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.599); catalogued as COSV99839077; called by muse, mutect2, varscan2
- NLGN3 | c.2192A>G p.Y731C (on ENST00000358741 / NM_181303.2; = p.Y711C on NM_018977.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 19/22 reads (86%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100704865; called by muse, mutect2, varscan2
- NLRP12 | c.2557C>A p.H853N | Missense Mutation (SNP) | VAF 10/29 reads (34%) | SIFT tolerated (0.08); PolyPhen benign (0.023); catalogued as rs1285704953, COSV100145500; called by muse, mutect2, varscan2
- NSMCE3 | c.211G>T p.A71S | Missense Mutation (SNP) | VAF 6/14 reads (43%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1220127008, COSV99722769; called by muse, mutect2
- OPRM1 | c.365C>G p.T122S | Missense Mutation (SNP) | VAF 26/57 reads (46%) | SIFT tolerated (0.2); PolyPhen probably damaging (1); catalogued as COSV100001863; called by muse, mutect2, varscan2
- PCDHA7 | c.2156C>G p.T719R | Missense Mutation (SNP) | VAF 13/36 reads (36%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.71); catalogued as rs782621405, COSV100970845, COSV65335104; called by muse, mutect2, varscan2
- PNPLA4 | c.352G>T p.A118S | Missense Mutation (SNP) | VAF 43/62 reads (69%) | SIFT tolerated (0.27); PolyPhen benign (0.007); catalogued as COSV101124406, COSV66853909; called by muse, mutect2, varscan2
- PSG9 | c.1043A>G p.E348G | Missense Mutation (SNP) | VAF 12/18 reads (67%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.676); catalogued as COSV99392437; called by muse, mutect2, varscan2
- PTPN12 | c.902A>T p.Y301F | Missense Mutation (SNP) | VAF 87/190 reads (46%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.573); catalogued as COSV99950492; called by muse, mutect2, varscan2
- RAI14 | c.1766A>G p.N589S | Missense Mutation (SNP) | VAF 25/69 reads (36%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.473); catalogued as COSV99463884; called by muse, mutect2, varscan2
- RBM12B | c.365A>G p.Y122C | Missense Mutation (SNP) | VAF 30/91 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.947); catalogued as rs773965515, COSV101197156; called by muse, mutect2, varscan2
- RCOR3 | c.1213A>G p.T405A | Missense Mutation (SNP) | VAF 19/55 reads (35%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100879624; called by muse, varscan2
- SIRT2 | c.607G>A p.E203K | Missense Mutation (SNP) | VAF 13/32 reads (41%) | SIFT tolerated (0.24); PolyPhen benign (0.118); catalogued as rs200953200, COSV50876633; called by muse, mutect2, varscan2
- SLC25A25 | c.798G>A p.Q266= | Splice Region (SNP) | VAF 4/28 reads (14%) | catalogued as COSV100895348; called by muse, mutect2
- SLC4A11 | c.2067G>T p.R689S | Missense Mutation (SNP) | VAF 9/20 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.73); catalogued as COSV101196067; called by muse, mutect2, varscan2
- TAPBPL | c.1222T>G p.L408V | Missense Mutation (SNP) | VAF 14/34 reads (41%) | SIFT tolerated (0.55); PolyPhen benign (0.034); catalogued as COSV99869422; called by muse, mutect2, varscan2
- TBC1D4 | c.2474A>T p.D825V | Missense Mutation (SNP) | VAF 30/58 reads (52%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.565); catalogued as rs531614085, COSV100884684; called by muse, mutect2, varscan2
- TCF15 | c.584G>T p.R195L | Missense Mutation (SNP) | VAF 33/72 reads (46%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.953); catalogued as COSV99856047; called by muse, mutect2, varscan2
- USP25 | c.2587G>C p.E863Q | Missense Mutation (SNP) | VAF 10/37 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.777); catalogued as COSV99584120; called by muse, mutect2, varscan2
- ZBTB38 | c.1868A>G p.N623S | Missense Mutation (SNP) | VAF 16/50 reads (32%) | SIFT tolerated (0.74); PolyPhen benign (0); catalogued as COSV100375797; called by muse, mutect2, varscan2
- ZNF208 | c.147G>T p.K49N | Missense Mutation (SNP) | VAF 41/94 reads (44%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.992); catalogued as COSV68111870; called by muse, mutect2, varscan2
- BBX | c.1217_1250del p.F406* | Frame Shift Del (DEL) | VAF 20/80 reads (25%) | called by mutect2, pindel
- CAPN3 | c.1789A>C p.K597Q | Missense Mutation (SNP) | VAF 22/60 reads (37%) | SIFT tolerated (0.11); PolyPhen benign (0.005); called by muse, varscan2
- CAPN3 | c.1795_1800+10del p.X599_splice | Splice Site (DEL) | VAF 19/63 reads (30%) | called by pindel, varscan2
- CCDC73 | c.1088del p.N363Mfs*38 | Frame Shift Del (DEL) | VAF 36/75 reads (48%) | called by mutect2, pindel, varscan2
- FMR1 | c.858del p.Q287Kfs*6 | Frame Shift Del (DEL) | VAF 95/127 reads (75%) | called by mutect2, varscan2
- KMT2D | c.13426del p.T4476Lfs*43 | Frame Shift Del (DEL) | VAF 17/41 reads (41%) | called by mutect2, pindel, varscan2
- MTSS1 | c.1673_1674insATA p.S557_Y558ins* | Nonsense Mutation (INS) | VAF 33/82 reads (40%) | called by mutect2, varscan2
- STK40 | c.851_852del p.R284Qfs*11 | Frame Shift Del (DEL) | VAF 6/16 reads (38%) | called by mutect2, varscan2
- ACAD8 | c.1038T>C p.D346= | Silent (SNP) | VAF 12/24 reads (50%) | catalogued as COSV99844431; called by muse, mutect2, varscan2
- ANGEL1 | c.642A>G p.P214= | Silent (SNP) | VAF 9/36 reads (25%) | catalogued as rs747135494, COSV99200441; called by muse, mutect2, varscan2
- FNDC1 | c.3586C>T p.L1196= | Silent (SNP) | VAF 19/36 reads (53%) | catalogued as rs1363894749, COSV51930936; called by muse, mutect2, varscan2
- HS3ST1 | c.441A>G p.R147= | Silent (SNP) | VAF 19/45 reads (42%) | catalogued as COSV99136879; called by muse, mutect2, varscan2
- IGFBP4 | c.546G>A p.L182= | Silent (SNP) | VAF 6/17 reads (35%) | catalogued as rs1308858958, COSV99511243; called by muse, mutect2, varscan2
- KAAG1 | c.141T>A p.A47= | Silent (SNP) | VAF 5/22 reads (23%) | catalogued as COSV99219780; called by muse, mutect2, varscan2
- MAGEC3 | c.159C>T p.A53= | Silent (SNP) | VAF 22/29 reads (76%) | catalogued as COSV74217417; called by muse, mutect2, varscan2
- MRPL45 | c.861G>C p.L287= | Silent (SNP) | VAF 19/39 reads (49%) | called by muse, mutect2, varscan2
- MYF6 | c.282G>A p.R94= | Silent (SNP) | VAF 8/24 reads (33%) | catalogued as COSV99952744; called by muse, mutect2, varscan2
- NEB | c.8187A>G p.K2729= | Silent (SNP) | VAF 21/70 reads (30%) | catalogued as rs1466641302, COSV99425277; called by muse, mutect2, varscan2
- NLRP5 | c.1503G>A p.L501= | Silent (SNP) | VAF 16/40 reads (40%) | catalogued as COSV101173623; called by muse, mutect2, varscan2
- PAH | c.1074A>G p.L358= | Silent (SNP) | VAF 17/50 reads (34%) | catalogued as CM130694, COSV100188235; called by muse, mutect2, varscan2
- PCDH17 | c.3126G>C p.A1042= | Silent (SNP) | VAF 17/36 reads (47%) | catalogued as rs534412507, COSV100931621, COSV100931767, COSV64975173; called by muse, mutect2, varscan2
- PCDHGC3 | c.603C>A p.A201= | Silent (SNP) | VAF 11/25 reads (44%) | catalogued as COSV99341219; called by muse, mutect2, varscan2
- PLCB2 | c.2400G>A p.E800= | Silent (SNP) | VAF 11/30 reads (37%) | catalogued as COSV99542316; called by muse, mutect2, varscan2
- PLD3 | c.189C>T p.G63= | Silent (SNP) | VAF 15/31 reads (48%) | catalogued as rs375652785; called by muse, mutect2, varscan2
- R3HCC1L | c.348A>G p.V116= | Silent (SNP) | VAF 27/40 reads (68%) | catalogued as COSV100107423; called by muse, mutect2, varscan2
- R3HDM2 | c.1401T>C p.L467= | Silent (SNP) | VAF 17/60 reads (28%) | catalogued as COSV100715374; called by muse, mutect2, varscan2
- SETD5 | c.4266G>A p.V1422= | Silent (SNP) | VAF 18/43 reads (42%) | catalogued as COSV56707324; called by muse, mutect2, varscan2
- TBR1 | c.492C>T p.S164= | Silent (SNP) | VAF 18/47 reads (38%) | catalogued as rs1272251716, COSV101271497; called by muse, mutect2, varscan2
- THUMPD1 | c.585A>G p.T195= | Silent (SNP) | VAF 57/177 reads (32%) | catalogued as rs1284171752, COSV101189719; called by muse, mutect2, varscan2
- ZNF677 | c.1590C>G p.L530= | Silent (SNP) | VAF 63/148 reads (43%) | catalogued as COSV100448061; called by muse, mutect2, varscan2
- FAM104A | c.322-2911C>T | Intron (SNP) | VAF 26/82 reads (32%) | catalogued as rs749964305, COSV55432604; called by muse, mutect2, varscan2
